CPTAC case C3N-02262 — Kidney — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/f70f02a7-eab5-4d55-8303-b4497a84f39e

Demographics
Sex at birth: male; Race: white; Year of birth: 1950; Vital status: Alive; Country of birth: Poland.

Diagnoses (1)
1. Renal cell carcinoma, NOS: ICD-O-3 morphology code: 8312/3; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Age at diagnosis: 67.3 years (24,568 days); Year of diagnosis: 2017; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: TX; AJCC pathologic N: NX; AJCC pathologic M: MX; AJCC pathologic stage: Stage I; Tumor grade: G3; Residual disease: RX; Days to last known disease status: 1,852 days (5.1 years); Progression or recurrence: yes; Days to recurrence: 1,401 days (3.8 years); Days to last follow up: 1,852 days (5.1 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 6 cm; Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 0; Margin status: Involved; Sarcomatoid present: No.

Follow-up (6 entries)
- Days to follow up: 389 days (1.1 years); Disease response: Tumor Free.
- Days to follow up: 754 days (2.1 years); Disease response: Tumor Free.
- Days to follow up: 1,202 days (3.3 years); Disease response: Tumor Free.
- Days to follow up: 1,520 days (4.2 years); Disease response: With Tumor.
- Days to follow up: 1,520 days (4.2 years); Disease response: Progressive Disease; Progression or recurrence: Yes; Days to recurrence: 1,401 days (3.8 years).
- Follow-up contact recording only the day: day 1,852.

Other clinical attributes
- Weight: 90 kg; Height: 165 cm; BMI: 33; Diabetes treatment type: Insulin.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 10; Cigarettes per day: 20; Tobacco smoking onset year: 1988; Tobacco smoking quit year: 1998; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker; Exposure duration years: 10.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-02262-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -7 days; Initial weight: 394 mg; Time between excision and freezing: 7 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-02262-22: Section location: Middle; Percent tumor nuclei: 80; Percent necrosis: 5.
- Sample C3N-02262-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -6 days; Method of sample procurement: Blood Draw.
